Somatic mutation profile of tumor specimen C3L-02555-03 (aliquot CPT0128370006) from CPTAC case C3L-02555, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 71.5 years (26,112 days).
Specimen C3L-02555-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a121344-1e0b-408c-a745-062523c1e363.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02555-31 (Blood Derived Normal), aliquot CPT0129420002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60f2b11f-b847-47db-8a58-4948c0bcf30b

The open-access MAF lists 34 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 6, RNA 2, Nonsense Mutation 1, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.331T>G p.W111G | Missense Mutation (SNP) | VAF 24/441 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as CM014084, COSV100911417, COSV64288542, COSV64290246; called by muse, mutect2
- CYP11B2 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 60/721 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as COSV59998336; called by muse, mutect2
- GDF15 | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); catalogued as COSV53251654, COSV53251828; called by muse, mutect2
- KRT72 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs766532753, COSV53373404; called by muse, mutect2
- LRFN3 | c.1523C>T p.T508M | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773956160; called by muse, mutect2
- MMP16 | c.1398G>T p.M466I | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1323199288, COSV54181118; called by muse, mutect2
- NACAD | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs950570302; called by muse, mutect2
- PCDHGB4 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 25/807 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.274); catalogued as rs1201903320, COSV53917768; called by muse, mutect2
- PLEC | c.5246G>A p.R1749Q (on ENST00000322810 / NM_201380.4; = p.R1639Q on NM_000445.5) | Missense Mutation (SNP) | VAF 75/864 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); catalogued as rs1041351510; called by muse, mutect2
- PPP1R12C | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 24/271 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs765132319; called by muse, mutect2
- SGSM1 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 29/388 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749576223, COSV68510943; called by muse, mutect2
- STK32C | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 35/452 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs377143071; called by muse, mutect2
- YEATS4 | c.419A>G p.D140G | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99924146; called by muse, mutect2, varscan2
- ZNF839 | c.406C>T p.R136W (on ENST00000558850 / NM_001267827.1; = p.R252W on NM_018335.5) | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99216272; called by muse, mutect2
- ASXL1 | c.3964C>T p.P1322S | Missense Mutation (SNP) | VAF 25/315 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- FER1L6 | c.4016G>A p.S1339N | Missense Mutation (SNP) | VAF 17/291 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- KRT1 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- MMP16 | c.1399A>T p.K467* | Nonsense Mutation (SNP) | VAF 11/172 reads (6%) | called by muse, mutect2
- MRGPRG | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 20/114 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- RPLP0 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 24/366 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.068); called by muse, mutect2
- SLC35D3 | c.643T>A p.W215R | Missense Mutation (SNP) | VAF 19/306 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TSHZ3 | c.1414A>G p.K472E | Missense Mutation (SNP) | VAF 33/527 reads (6%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.971); called by muse, mutect2
- WWC3 | c.2491C>A p.P831T | Missense Mutation (SNP) | VAF 11/304 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.109); called by muse, mutect2
- ZBTB16 | c.1096A>T p.M366L | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2
- ZNF516 | c.3112G>A p.V1038I | Missense Mutation (SNP) | VAF 32/378 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- ESPL1 | c.1332G>T p.L444= | Silent (SNP) | VAF 26/296 reads (9%) | called by muse, mutect2
- KIF17 | c.369G>A p.E123= | Silent (SNP) | VAF 69/582 reads (12%) | called by muse, mutect2, varscan2
- NANP | c.669G>T p.P223= | Silent (SNP) | VAF 12/223 reads (5%) | catalogued as rs370156946; called by muse, mutect2
- REXO1 | c.3348C>T p.A1116= | Silent (SNP) | VAF 10/152 reads (7%) | catalogued as rs539586748, COSV99402184; called by muse, mutect2
- SVEP1 | c.3636G>A p.G1212= | Silent (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- TIGD3 | c.1164C>T p.S388= | Silent (SNP) | VAF 28/306 reads (9%) | catalogued as rs745380080; called by muse, mutect2
- AC244197.3 | c.-1632G>T | 5'UTR (SNP) | VAF 22/313 reads (7%) | called by muse, mutect2
- AC245047.1 | n.46C>G | RNA (SNP) | VAF 16/322 reads (5%) | called by muse, mutect2
- SPATA31C1 | n.2095G>A | RNA (SNP) | VAF 45/804 reads (6%) | catalogued as rs1167407759; called by muse, mutect2
